Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2ME, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2ME-06A (Metastatic).

[page 1 of 2]
PathNet History Upload External
Client

DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to: N/A

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORIC REQUEST DETAILS

CLINICAL NOTES

M57. (R) back melanoma (0.64mm) excised in
FNA ?melanoma.

Now mass (L) groin.

SPECIMEN INFORMATION

(L) ilio-inguinal groin dissection.

MACROSCOPIC DESCRIPTION

Two specimens received.

I. "Left ilio-inguinal contents". A piece of fatty tissue, 290 x 85 x 50mm with an overlying ellipse of skin 215 x 15mm. There are no abnormalities seen on the skin surface. The specimen was examined for lymph nodes. In the deep portion of the specimen there is a tumour nodule 38mm in diameter which abuts the deep surgical margin. Sectioning reveals that it has a soft pale-tan and dark-brown appearance.

A. Section through tumour deposit.

B&C. 1 node in two pieces.

D. 4 nodes.

E. 1 node in three pieces.

F. 3 nodes.

G. 1 node in two pieces.

H. 1 node in three pieces.

J. 2 nodes.

II. "Left external iliac & obturator nodes". An irregularly shaped piece of fatty tissue, 70 x 35 x 15mm. The specimen was examined for lymph nodes.

A. 1 node in two pieces (designated node A)

B. 2 nodes.

C&D. Each 1 node in two pieces.

E. ?3 nodes.

F. ?1 node flat node in two pieces.

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, inguinal

C77.4

lw 8/24/4

MICROSCOPIC REPORT

I-II. Metastatic malignant melanoma is present in 1 (one) of 23 nodes. The deposit is in the ilio-inguinal group (block IA).

It has a pleomorphic epithelioid/"plasmacytoid" appearance, scant pigment and a mitotic rate of 2/mm2. Only minor TILs are seen near the edge of the

[page 2 of 2]
Requested by: N/A

MRN/Name:

Location:

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

tumour, but no regression. It fills the node in a solid fashion.
No extra-nodal spread. The tumour is 0.2mm clear of the surgical line of excision.

Electronic signature

DIAGNOSIS

(L) ilio-inguinal dissection - Metastatic MALIGNANT MELANOMA (1/23).

SUMMARY / KEY WORDS

Inguinal lymph node - Malignant melanoma, metastatic - 1/23

Source: NCI Genomic Data Commons file 18adbbef-f2e3-4098-9a0d-443c632f349a (TCGA-EE-A2ME.BC84FD0C-9539-4D28-BBF6-B95D6770E404.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).